Somatic mutation profile of tumor specimen BA2868D (aliquot aq-BA2868D) from BEATAML1.0 case 2442, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.4 years (25,336 days).
Specimen BA2868D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1944d3a-80b4-47d3-b586-6e9c1cf3be20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2424D (Solid Tissue Normal), aliquot aq-BA2424D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5896da7f-060f-4d5c-869e-d4a83ad0962d

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, Frame Shift Ins 1, Splice Site 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C14orf39 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58779470; called by muse, mutect2, varscan2
- FREM3 | c.5390G>A p.R1797H | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201583533; called by muse, mutect2, varscan2
- PIP5K1B | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs748104975; called by muse, mutect2, varscan2
- PLA2G2E | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139719874; called by muse, mutect2, varscan2
- SLCO1C1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs565521634; called by muse, mutect2, varscan2
- UGT1A6 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59381633; called by muse, mutect2, varscan2
- WT1 | c.1101dup p.R368Tfs*5 | Frame Shift Ins (INS) | VAF 94/223 reads (42%) | catalogued as COSV100189346, COSV60065589, COSV60066153, COSV60066283, COSV60067539, COSV60069909, COSV60077657, COSV60077667, COSV60077683, COSV60078403, COSV60079676, COSV60084998, COSV60085351; called by mutect2, pindel, varscan2
- WT1 | c.887+1G>A p.X296_splice | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as CS156573; called by muse, mutect2, varscan2
- CEBPA | c.117del p.A40Rfs*120 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2
- EXPH5 | c.5468G>T p.S1823I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2
- IQCN | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNG1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11G2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POTEE | c.594A>T p.Q198H | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ARHGEF40 | c.2523C>G p.A841= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.11466C>T p.H3822= | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- MICAL3 | c.5643C>T p.G1881= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1476851742, COSV71588023; called by muse, mutect2
- CDH13 | c.45+78030G>A | Intron (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- CPED1 | c.2311-4557T>C | Intron (SNP) | VAF 32/88 reads (36%) | catalogued as rs532226040; called by muse, mutect2, varscan2
- MIR612 | n.99C>A | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
